Gene-level copy-number profile of tumor specimen TCGA-86-8358-01A from TCGA case TCGA-86-8358, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 44.9 years (16,409 days).
Specimen TCGA-86-8358-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.3e2f489f-0b9a-4ae1-8d8f-f452e3765146.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8358-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/47cc96cb-6f4a-4cd7-b122-b084f4be01de

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 1,275; copy number 2: 4,814; copy number 3: 13,405; copy number 4: 19,468; copy number 5: 10,119; copy number 6: 3,143; copy number 7: 4,069; copy number 8: 2,257; copy number 9: 534; copy number 10: 90; copy number 11: 288; copy number 12: 215; copy number 13: 26; copy number 15: 21; copy number 18: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8358-01A-11D-2322-01): tumor purity 0.72, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:65,843,890–65,954,558, 3 genes: RPL17P17, MAGI1-IT1, MAGI1-AS1.
- chr18:8,133,203–8,832,778, 16 genes: AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1.
- chr18:10,525,905–12,129,764, 52 genes: NAPG, AP001099.1, LINC01887, AP001180.3, CCDC58P1, AP001180.2, AP001180.5, PMM2P1, AP001180.1, PIEZO2, AP001180.4, KIAA0895LP1, MIR6788, AP005120.1, AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1.
- chr21:39,184,176–39,321,559, 1 gene (within-gene range 0–6): BRWD1.
- chr21:39,216,624–39,323,218, 5 genes: TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,186 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:19,471,296–31,329,146, 107 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr6:38,714,051–44,830,188, 182 genes, copy number 9–11 (broad region; genes not listed).
- chr7:70,972–20,590,085, 327 genes, copy number 11–12 (broad region; genes not listed).
- chr7:57,140,112–62,275,678, 61 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr14:30,541,776–32,203,269, 43 genes, copy number 10: SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8.
- chr14:32,329,298–32,837,684, 1 gene, copy number 9 (within-gene range 7–9): AKAP6.
- chr14:32,879,246–41,298,734, 129 genes, copy number 9–12 (broad region; genes not listed).
- chr14:59,595,976–59,870,776, 1 gene, copy number 9 (within-gene range 7–9): RTN1.
- chr14:59,919,423–62,515,123, 52 genes, copy number 9: AL133299.1, LRRC9, AL157911.1, PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A, LINC02322, C14orf39, RBM8B, GNRHR2P1, SALL4P7, SIX6, AL049874.3, AL049874.4, AL049874.2, AL049874.1, SALRNA1, SIX1, SIX4, MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P, SLC38A6, PRKCH, TMEM30B, AL359220.1, AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3, AL137129.1, SNAPC1, AL137918.1, SYT16, COX4I1P1, AL390816.1, AL390816.2, LINC00643, LINC00644, AL390816.3, AL389895.1.
- chr14:93,895,762–94,675,829, 30 genes, copy number 9: AL132642.2, FAM181A-AS1, FAM181A, ASB2, AL132642.1, MIR4506, CCDC197, OTUB2, DDX24, IFI27L1, IFI27, IFI27L2, PPP4R4, SERPINA10, SERPINA6, SERPINA2, SERPINA1, AL132708.1, SERPINA11, SERPINA9, SERPINA12, AL132990.1, SERPINA4, SERPINA5, AL049839.2, AL049839.3, SERPINA3, ADIPOR1P2, SERPINA13P, AL049839.1.
- chr18:1,509,022–2,616,635, 12 genes, copy number 18 (within-gene range 3–18): AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3.
- chr18:12,785,478–13,216,367, 10 genes, copy number 12 (within-gene range 7–12): PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1.
- chr18:13,234,945–13,366,243, 5 genes, copy number 12: AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1.
- chr18:14,946,267–15,330,282, 16 genes, copy number 9: LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr18:23,453,287–28,824,826, 87 genes, copy number 9–15 (broad region; genes not listed).
- chr18:31,498,177–32,773,023, 38 genes, copy number 10 (within-gene range 3–10): DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14.
- chr18:33,552,123–36,780,055, 49 genes, copy number 9–15 (within-gene range 6–15): AC091198.1, ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1.
- chr18:39,206,917–39,924,840, 10 genes, copy number 11 (within-gene range 4–11): MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902.
- chr19:35,399,511–35,738,878, 26 genes, copy number 13 (within-gene range 8–13): LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN, SBSN, GAPDHS, TMEM147-AS1, TMEM147, ATP4A, AD000090.1, PMIS2, LINC01766, AC002115.1, HAUS5, RBM42, ETV2, COX6B1, UPK1A, UPK1A-AS1, TYMSP2, ZBTB32, KMT2B.

Autosomal genes at a single copy (total copy number 1): 111. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
